Somatic mutation profile of tumor specimen TCGA-FY-A3TY-01A (aliquot TCGA-FY-A3TY-01A-11D-A22Z-08) from TCGA case TCGA-FY-A3TY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 61.8 years (22,556 days).
Specimen TCGA-FY-A3TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ffe9007-89b1-4344-822e-b6a6785adc21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3TY-10A (Blood Derived Normal), aliquot TCGA-FY-A3TY-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e30f17c-fee5-4eee-ab1a-ea08f7f988e3

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB11 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as rs868669576, COSV55589511; called by muse, mutect2, varscan2
- PCDH17 | c.3439C>T p.Q1147* | Nonsense Mutation (SNP) | VAF 19/165 reads (12%) | catalogued as COSV100931911; called by muse, mutect2, varscan2
- UBE2NL | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs782280790; called by muse, mutect2, varscan2
- SPSB3 | c.253C>T p.L85= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99236676; called by muse, mutect2
